Somatic mutation profile of tumor specimen TCGA-FG-8187-01A (aliquot TCGA-FG-8187-01A-11D-2253-08) from TCGA case TCGA-FG-8187, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 32.0 years (11,684 days).
Specimen TCGA-FG-8187-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b855437b-9393-4a6a-9463-df53df96cee0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FG-8187-10A (Blood Derived Normal), aliquot TCGA-FG-8187-10A-01D-2253-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e019bd3-fbcd-407d-b5d9-5d2911047ce4

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 5, Silent 4, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 42/154 reads (27%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- KCNQ4 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61273999; called by muse, varscan2
- OR8K1 | c.689C>T p.A230V | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.367); catalogued as COSV54401386, COSV54402508; called by muse, mutect2, varscan2
- PBX4 | c.1048C>T p.Q350* | Nonsense Mutation (SNP) | VAF 4/30 reads (13%) | catalogued as rs1280691706, COSV52062425; called by muse, mutect2, varscan2
- RIPK4 | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 71/161 reads (44%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.608); catalogued as rs563560488, COSV60188376; called by muse, mutect2, varscan2
- TEKT1 | c.1132G>A p.V378I | Missense Mutation (SNP) | VAF 14/159 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as COSV58623808, COSV58624943; called by muse, mutect2
- TMTC4 | c.2135_2137del p.S712del (on ENST00000376234 / NM_001350577.2; = p.S731del on NM_032813.5 and 2 other RefSeq transcripts) | In Frame Del (DEL) | VAF 21/247 reads (9%) | catalogued as rs1384870152; called by mutect2, pindel
- CUBN | c.5055C>T p.G1685= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as rs565623595, COSV64720398; called by muse, mutect2, varscan2
- HOXD3 | c.348A>G p.P116= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as COSV50882225; called by muse, mutect2
- ZBTB21 | c.2722C>T p.L908= | Silent (SNP) | VAF 9/138 reads (7%) | catalogued as COSV60404818; called by muse, mutect2
- ZDBF2 | c.6684G>A p.S2228= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as rs769931510, COSV100985602, COSV65624129; called by muse, mutect2, varscan2
